Somatic mutation profile of tumor specimen MP2PRT-PAPEZL-TMP1-A (aliquot MP2PRT-PAPEZL-TMP1-A-1-0-D-A834-36) from MP2PRT case MP2PRT-PAPEZL, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.2 years (1,904 days).
Specimen MP2PRT-PAPEZL-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9982a5d7-0567-4f32-98c8-e890a0fd1788.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPEZL-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPEZL-NB1-A-1-0-D-A834-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/827a2705-1fe0-41c0-82f7-38db494e3e83

The open-access MAF lists 23 somatic variants for this specimen: 17 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 5, 3'Flank 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRL2 | c.1083G>C p.Q361H | Missense Mutation (SNP) | VAF 136/348 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.696); catalogued as COSV99592150; called by muse, mutect2, varscan2
- ARHGAP45 | c.1630G>A p.V544M | Missense Mutation (SNP) | VAF 80/564 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV104398967; called by muse, mutect2, varscan2
- CLIC2 | c.28G>A p.V10M | Missense Mutation (SNP) | VAF 170/349 reads (49%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV58935904; called by muse, mutect2, varscan2
- KNDC1 | c.3761C>T p.T1254M | Missense Mutation (SNP) | VAF 194/453 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs769180488, COSV58834403; called by muse, mutect2, varscan2
- MTFR1 | c.541G>T p.G181C | Missense Mutation (SNP) | VAF 14/124 reads (11%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.813); catalogued as rs780225005; called by mutect2, varscan2
- NEB | c.3245C>T p.A1082V | Missense Mutation (SNP) | VAF 102/232 reads (44%) | SIFT tolerated (0.29); PolyPhen benign (0.047); catalogued as rs752809792, COSV51417803, COSV51462841; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NSD2 | c.3374A>G p.D1125G | Missense Mutation (SNP) | VAF 130/310 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56397674; called by muse, mutect2, varscan2
- RREB1 | c.3524G>A p.S1175N | Missense Mutation (SNP) | VAF 39/711 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV58567227; called by muse, mutect2
- SRSF8 | c.236A>T p.E79V | Missense Mutation (SNP) | VAF 196/488 reads (40%) | SIFT tolerated (0.51); PolyPhen benign (0.18); catalogued as rs1555107040; called by mutect2, varscan2
- USP15 | c.2621G>A p.R874H (on ENST00000280377 / NM_001351159.2; = p.R845H on NM_006313.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 95/288 reads (33%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.717); catalogued as COSV54788718; called by muse, mutect2, varscan2
- ZFP42 | c.865T>C p.S289P | Missense Mutation (SNP) | VAF 23/418 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1157219525; called by muse, mutect2
- AMER1 | c.2449G>A p.D817N | Missense Mutation (SNP) | VAF 48/441 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.351); called by muse, mutect2, varscan2
- CNGB1 | c.516G>T p.Q172H | Missense Mutation (SNP) | VAF 32/420 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.044); called by muse, mutect2
- IGHV1-69 | chr14:106714682 del TCTC | Missense Mutation (DEL) | VAF 5/16 reads (31%) | called by pindel*, varscan2
- IGLV4-69 | c.357_358insTC | In Frame Ins (INS) | VAF 44/160 reads (28%) | called by mutect2, pindel*, varscan2
- PNMA8C | c.487G>A p.V163I | Missense Mutation (SNP) | VAF 24/546 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.018); called by muse, mutect2
- UTP20 | c.2734G>T p.A912S | Missense Mutation (SNP) | VAF 9/236 reads (4%) | SIFT tolerated (0.27); PolyPhen benign (0.033); called by muse, mutect2
- CFLAR | c.802C>A p.R268= | Silent (SNP) | VAF 76/176 reads (43%) | called by muse, mutect2, varscan2
- F5 | c.2292C>T p.F764= | Silent (SNP) | VAF 16/368 reads (4%) | catalogued as rs536614946, COSV63124055; called by muse, mutect2
- HAS1 | c.1347G>A p.A449= | Silent (SNP) | VAF 282/722 reads (39%) | catalogued as rs754658488; called by muse, mutect2, varscan2
- RBP4 | c.25C>T p.L9= | Silent (SNP) | VAF 50/604 reads (8%) | catalogued as rs1343319660; called by muse, mutect2
- SEC22C | c.633A>G p.E211= | Silent (SNP) | VAF 16/336 reads (5%) | called by muse, mutect2
- IGKV1D-16 | chr2:90100738 ins TCCC | 3'Flank (INS) | VAF 98/162 reads (60%) | called by mutect2, pindel, varscan2
